Gene-level copy-number profile of tumor specimen AP-RBLG-HM from APOLLO case AP-RBLG, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3.
Specimen AP-RBLG-HM: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e6273ec3-d5b2-4b33-bc42-87bc306f1967.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-RBLG-LX (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/e56b0dac-42f4-43d7-baa2-4a398710fa3e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 127; copy number 1: 12,883; copy number 2: 38,118; copy number 3: 5,537; copy number 4: 1,710; copy number 5: 14.

Homozygous deletions (total copy number 0; autosomes only): 123 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:187,970,273–188,161,157, 8 genes: AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434.
- chr5:177,809,407–178,150,568, 12 genes (within-gene range 0–1): AC106795.1, OR1X5P, AC140125.3, AC106795.3, AC106795.2, AC106795.5, SUDS3P1, PROP1, FAM153CP, AC136632.1, N4BP3, RMND5B.
- chr9:23,955,760–27,543,902, 31 genes (within-gene range 0–1): AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1.
- chr9:38,147,428–39,039,594, 22 genes: U8, AL135785.1, ALDH1B1, IGFBPL1, AL390726.5, ARMC8P1, TCEA1P3, GAS2L1P1, VN1R48P, AL390726.1, FAM220BP, AL390726.4, FAM95C, AL390726.3, AL390726.2, SNX18P3, ANKRD18A, FAM201A, YWHABP1, RNU6-765P, AL845311.1, VN2R3P.
- chr9:63,974,762–66,642,277, 50 genes: AL163540.1, U6, ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P, CDRT15P12, RBPJP2, RAB28P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:221,701,424–221,742,089, 1 gene, copy number 5: DUSP10.
- chr5:58,198–257,082, 8 genes, copy number 5: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA.
- chr5:269,858–271,516, 1 gene, copy number 5: AC021087.1.
- chr19:58,573,503–58,605,223, 4 genes, copy number 5 (within-gene range 2–5): CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.

Autosomal genes at a single copy (total copy number 1): 11,594. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
